Surgical pathology report (de-identified scan), TCGA case TCGA-55-7281, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-7281-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

COPY TO: [REDACTED]

Pre-Op Diagnosis
Lung cancer, right lung
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Five parts

Container labeled "[REDACTED] 1 - right chest level 7 lymph node" are two nodular portions of gray tan to pink fleshy tissue each of which is surrounded by yellow adipose tissue. The portions are 1.2 x 0.9 x 0.3 cm and 2.0 x 1.2 x 0.3 cm. Specimen entirely submitted in a single cassette.

Container labeled "[REDACTED] 2 - level 9 lymph node right chest" is 1.2 x 1.0 x 0.3 cm portion of tan pink fibroadipose tissue having a 0.4 cm in greatest dimension gray tan fleshy nodule. Specimen entirely submitted in a single cassette.

Container labeled "[REDACTED] 3 - right chest level 10 lymph node" are 1.4 x 1.0 x 0.4 cm of soft rubbery focally shaggy fleshy gray black tissue fragments which are entirely submitted in a single cassette.

Container labeled "[REDACTED] 4 - upper and middle lobe of right lung" is a partially sectioned bilobed portion of recognizable pulmonary parenchyma grossly consistent with right upper and middle lobes of lung. The specimen as received weighs 166 grams and measures overall 19.6 x 11.0 x 2.5 cm. The margin of resection

[page 2 of 3]
includes a secondary bronchus at a point 0.4 cm from the bifurcation of the tertiary bronchi. The pleura is wrinkled tan pink to red with moderate anthracotic streaking. Noted on the medial aspect within 0.2 cm of the parenchymal hilar margin and 2.8 cm from the nearest bronchial margin there is a previously sectioned 2.2 x 2.0 x 1.8 cm fairly well defined gray tan fibrotic nodular lesion with the lesion extending into the middle lobe parenchyma. Multiple staples overlie the lesion at the parenchymal margin. Removal of these staples obscures the actual margin. However, the lesion gross appears to be seen within 0.2 cm of the medial parenchymal margin. The bronchial connection is grossly identified. The lesion has a gritty gray tan fibrotic cut surface. The remaining parenchyma is spongy and tan pink to red with moderate anthracotic streaking. No additional gross lesions are identified. Also received in the same container are three tissue cassettes each labeled [REDACTED]. Representative sections are submitted labeled as follows: A - shave bronchial margin; B-E - entire remaining lesion and surrounding tissue; F - representative random upper lobe parenchyma; G - representative random middle lobe parenchyma.

Container labeled "[REDACTED] 5 - right chest level 4 lymph node" are 2.0 x 1.5 x 0.4 cm of soft rubbery shaggy gray brown to black fleshy tissue fragments which are entirely submitted in a single cassette.

[REDACTED]

Microscopic Description:

The slides labeled [REDACTED] are examined. See diagnosis.

Final Diagnosis

Lymph nodes, level 7, right chest (biopsy):

Reactive sinus histiocytosis and anthracosilicosis, no metastatic carcinoma identified within two lymph nodes (0/2). PAS 4

Lymph node, level 9, right chest (biopsy):

Reactive sinus histiocytosis and anthracosilicosis, no metastatic carcinoma identified within one lymph node (0/1). PAS 4

Lymph node, level 10, right chest (biopsy):

Reactive sinus histiocytosis and anthracosilicosis, no metastatic carcinoma identified within one lymph node (0/1). PAS 4

Right lung, upper and middle lobes:

Tumor characteristics:

Histologic type: Adenocarcinoma

Location of tumor: Right lung

Size: 2.2 x 2.0 x 1.8 cm in greatest dimensions

Grade: Moderate to poorly differentiated

Pleural invasion: Not identified

Lymphovascular space invasion: Yes

Surgical margin status:

Tumor distance from bronchial margin: 2.8 cm

Tumor distance from parenchymal margin: 0.2 cm

Parenchymal margin: No carcinoma identified

Lymph node status:

See above and below diagnoses. PAS 9

Other findings:

Emphysematous changes and subpleural fibrosis. PAS 4

Lymph node, level 4, right chest:

Multiple fragments of lymph node demonstrating reactive sinus

[REDACTED]

[page 3 of 3]
histiocytosis, anthracosilicosis
and benign fibrous nodule, no carcinoma identified. PAS 4
SPC-A

Stage: pT1 N0

CPT: 88309, 88305 x 4

Comments

Clinical correlation and followup is recommended.

At the request of the undersigned pathologist, these slides have
been additionally reviewed by Dr. [REDACTED] who concurs with the
diagnosis.

This test has been finalized at the [REDACTED] Campus.

<Sign Out Dr. Signature>

[REDACTED], M.D., Ph.D

[REDACTED]

Source: NCI Genomic Data Commons file 726de985-d338-4919-bc63-26d350e25b4f (TCGA-55-7281.8C99C857-2AB0-4481-AB5D-8ED971968620.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).